Gene-level copy-number profile of tumor specimen TCGA-R6-A6XG-01B from TCGA case TCGA-R6-A6XG, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; Tumor grade: G2; Age at diagnosis: 64.3 years (23,484 days).
Specimen TCGA-R6-A6XG-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.946e8a67-96ca-43d8-89fb-bc9fb5bcdce1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-R6-A6XG-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b45f0854-d25a-4ce9-b13e-115732e45a85

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 216; copy number 1: 4,260; copy number 2: 26,094; copy number 3: 21,308; copy number 4: 6,007; copy number 5: 1,205; copy number 6: 358; copy number 7: 45; copy number 8: 43; copy number 9: 55; copy number 10: 37; copy number 11: 23; copy number 14: 17; copy number 15: 112; copy number 25: 3; copy number 45: 27; copy number 51: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-R6-A6XG-01B-11D-A33D-01): tumor purity 0.79, ploidy 2.57, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 216 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:141,862,860–146,050,366, 192 genes (broad region; genes not listed).
- chr7:146,208,665–146,311,822, 2 genes: AC073418.1, Y_RNA.
- chr8:34,784,028–36,936,125, 22 genes (within-gene range 0–2): LINC01288, AC087343.1, AC099685.1, UNC5D, AC090740.1, LSM12P1, AC105230.1, AC124290.1, AC124290.2, AC124290.3, MTCYBP19, MTND6P19, MTND5P41, AP006245.1, RNU6-533P, AP006245.2, AC090809.1, RPL23P10, RNA5SP264, KCNU1, AC124076.1, TPT1P8.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,926 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:60,719,222–62,611,327, 13 genes, copy number 5: GAPDHP41, AL590227.1, AL512427.2, AL512427.1, RBBP4P3, AL356131.1, MTRNR2L9, KHDRBS2-OT1, KHDRBS2, AL355347.1, DHFRP5, AL355375.1, AL355375.2.
- chr7:174,920–5,854,365, 124 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr7:6,952,625–14,974,777, 82 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr7:47,252,139–48,852,898, 17 genes, copy number 14: AC087175.1, TNS3, LINC01447, C7orf65, PKD1L1, LINC00525, C7orf69, AC069282.1, HUS1, SUN3, C7orf57, UPP1, ABCA13, AC091770.1, LINC02838, AC004899.1, AC004899.2.
- chr7:85,381,118–97,740,472, 169 genes, copy number 5 (broad region; genes not listed).
- chr7:103,297,435–104,907,232, 14 genes, copy number 5 (within-gene range 4–5): PMPCB, DNAJC2, PSMC2, RPS29P16, SLC26A5, Y_RNA, Y_RNA, AC005064.1, RELN, RN7SKP86, ORC5, LHFPL3, EIF4BP6, LHFPL3-AS1.
- chr8:123,416,726–129,683,770, 95 genes, copy number 5–9 (within-gene range 3–9) (broad region; genes not listed).
- chr12:23,529,504–24,562,544, 1 gene, copy number 25 (within-gene range 4–45): SOX5.
- chr12:24,212,421–34,249,958, 216 genes, copy number 5–51 (broad region; genes not listed).
- chr13:46,771,256–47,307,301, 4 genes, copy number 7: ESD, HTR2A, HTR2A-AS1, GNG5P5.
- chr13:48,653,711–48,771,827, 2 genes, copy number 5: CYSLTR2, PSME2P2.
- chr13:48,975,912–49,209,779, 1 gene, copy number 5 (within-gene range 2–5): FNDC3A.
- chr13:49,044,079–52,739,820, 99 genes, copy number 5–6 (broad region; genes not listed).
- chr13:54,572,354–56,885,602, 11 genes, copy number 6 (within-gene range 2–6): AL442636.1, AL512655.1, AL390964.1, LINC02335, AL139038.1, MIR5007, AL354821.1, HNF4GP1, AL138997.1, SPATA2P1, RN7SKP6.
- chr13:93,818,424–93,836,144, 1 gene, copy number 5: GPC6-AS2.
- chr16:5,239,802–7,713,340, 1 gene, copy number 6 (within-gene range 2–6): RBFOX1.
- chr16:5,596,856–15,154,564, 204 genes, copy number 6–7 (within-gene range 3–7) (broad region; genes not listed).
- chr16:23,835,983–24,220,611, 1 gene, copy number 5 (within-gene range 3–5): PRKCB.
- chr16:24,098,239–35,912,516, 560 genes, copy number 5–11 (broad region; genes not listed).
- chr18:20,946,906–31,426,988, 160 genes, copy number 6–15 (within-gene range 3–15) (broad region; genes not listed).
- chr19:28,065,267–34,780,021, 151 genes, copy number 5–6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,868. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
